FM case AD11947 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Germ Cell Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/2c91a47b-76a2-462d-bf3e-48ff9c65434f

Female, 19.1 years: Germ cell tumor, NOS (ICD-O-3 9064/3) of the ovary; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
